CCDI case PBBYKS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/5188b374-df1f-412c-b00e-68b2d2fc007a

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Pleomorphic xanthoastrocytoma: ICD-O-3 morphology code: 9424/3; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 15.1 years (5,517 days).

Biospecimens (3 samples)
- Sample 0DLX4I: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DLX55: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DLX5E: Tissue type: Tumor; Specimen type: Solid Tissue.
